CCDI case PBCLPG — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Bones, joints and articular cartilage of other and unspecified sites.
https://portal.gdc.cancer.gov/cases/0f0b265e-f380-4b3f-baad-b6d2f84788c1

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8900/3; Tissue or organ of origin: Pelvis, NOS; Age at diagnosis: 2.9 years (1,057 days).

Biospecimens (3 samples)
- Sample 0DUNOC: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DUNP4: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DUNQ0: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
